Gene-level copy-number profile of tumor specimen TCGA-VS-A958-01A from TCGA case TCGA-VS-A958, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 46.3 years (16,905 days).
Specimen TCGA-VS-A958-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.1f8efe9c-6f82-4894-a5e9-0771470c1c0d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A958-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d3e8ab5e-b009-4675-a229-c289554ffe14

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 3,642; copy number 2: 51,616; copy number 3: 1,750; copy number 4: 2,798.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A958-01A-11D-A42N-01): tumor purity 0.48, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr4:69,721,167–70,085,290, 11 genes (within-gene range 0–1): SULT1B1, SULT1D1P, AC108941.3, SULT1E1, AC108941.1, CSN1S1, CSN2, STATH, HTN3, HTN1, CSN1S2AP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,642. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
